CPTAC case C3N-02379 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cfc61554-67b2-4ab4-813c-5f9b72bc325e

Demographics
Sex at birth: female; Race: asian; Year of birth: 1960; Vital status: Dead; Days to death: 443 days (1.2 years); Year of death: 2018; Country of birth: China.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 57.0 years (20,827 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2a; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 443 days (1.2 years); Progression or recurrence: no; Days to last follow up: 429 days (1.2 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4 cm; Lymph node involvement: Positive; Lymph nodes positive: 4; Lymph nodes tested: 24; Margin status: Uninvolved.

Follow-up (2 entries)
- Days to follow up: 364 days; Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 429 days (1.2 years); Disease response: Tumor Free; Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 65 kg; Height: 168 cm; BMI: 23.03; DLCO (% of predicted): 95; FEV1/FVC before bronchodilator (%): 88; FEV1 before bronchodilator (% of reference): 76.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (9 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02379-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -7 days; Initial weight: 100 mg; Time between clamping and freezing: 38 minutes; Time between excision and freezing: 22 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02379-21: Section location: Right Upper Lobe; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3N-02379-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -7 days; Initial weight: 100 mg; Time between clamping and freezing: 38 minutes; Time between excision and freezing: 22 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02379-22: Section location: Right Upper Lobe; Percent tumor nuclei: 70; Percent necrosis: 5.
- Sample C3N-02379-03: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -7 days; Initial weight: 100 mg; Time between clamping and freezing: 38 minutes; Time between excision and freezing: 22 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Samples C3N-02379-31, C3N-02379-32, C3N-02379-72, C3N-02379-73, C3N-02379-74 (5 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
- Sample C3N-02379-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -7 days; Method of sample procurement: Blood Draw.
